Somatic mutation profile of tumor specimen C3N-01521-01 (aliquot CPT0076680009) from CPTAC case C3N-01521, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 75.8 years (27,702 days).
Specimen C3N-01521-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eceb78d5-3c82-4ddf-a8c8-7c19fd1a627f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01521-71 (Blood Derived Normal), aliquot CPT0076760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7483ad6-2a98-4ae7-91f0-b161371c3bc1

The open-access MAF lists 47 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 11, Intron 3, 5'UTR 3, Nonsense Mutation 2, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 72/221 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 211/298 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AC244258.1 | n.244T>A | Splice Region (SNP) | VAF 48/114 reads (42%) | catalogued as rs745514437; called by muse, mutect2, varscan2
- ARID1A | c.3524dup p.L1176Ifs*17 | Frame Shift Ins (INS) | VAF 65/143 reads (45%) | catalogued as COSV99055478; called by mutect2, pindel, varscan2
- C10orf71 | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs755363464; called by muse, mutect2
- FAN1 | c.2762G>A p.R921H | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377084092; called by mutect2, varscan2
- HK2 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.614); catalogued as rs368353026; called by muse, mutect2, varscan2
- IFT20 | c.227G>A p.R76Q (on ENST00000395418 / NM_001267776.2; = p.S115= on NM_174887.4) | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs139696386; called by muse, mutect2, varscan2
- LRP1 | c.12035G>C p.R4012T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV54529140; called by muse, mutect2
- MAP1A | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs986114944, COSV55806664; called by muse, mutect2, varscan2
- NOX5 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs543816309; called by muse, mutect2, varscan2
- PNMA1 | c.220T>G p.Y74D | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs1566575323; called by muse, mutect2, varscan2
- RRAS2 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 489/575 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56329970, COSV56331263; called by muse, mutect2, varscan2
- RTN2 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 165/245 reads (67%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.832); catalogued as rs774982121, COSV55594165; called by muse, mutect2, varscan2
- SCAF11 | c.3233G>A p.R1078H | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs370077453; called by muse, mutect2, varscan2
- SCN7A | c.3910G>A p.A1304T | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs537278563; called by muse, mutect2, varscan2
- VGLL1 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 237/446 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778398693; called by muse, mutect2, varscan2
- VIPR1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs759116545; called by muse, mutect2, varscan2
- ZNF804A | c.3349G>A p.A1117T | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs201884581, COSV56455234; called by muse, mutect2, varscan2
- ABCC1 | c.746C>G p.T249R | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DDB1 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, varscan2
- EMC1 | c.2875G>A p.D959N | Missense Mutation (SNP) | VAF 83/132 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF15 | c.3704A>C p.N1235T | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PPIA | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 103/200 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- RAPGEF4 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 19/185 reads (10%) | called by muse, mutect2, varscan2
- SC5D | c.427C>A p.H143N | Missense Mutation (SNP) | VAF 37/353 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- SC5D | c.758C>G p.S253* | Nonsense Mutation (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- SYNGR3 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- USP22 | c.609del p.F204Sfs*52 | Frame Shift Del (DEL) | VAF 71/128 reads (55%) | called by mutect2, pindel, varscan2
- DCHS2 | c.1296G>A p.P432= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs546617253; called by muse, mutect2, varscan2
- DCP1B | c.999G>A p.Q333= | Silent (SNP) | VAF 91/409 reads (22%) | catalogued as rs1209617569; called by muse, mutect2, varscan2
- DNAJB12 | c.579G>A p.A193= (on ENST00000338820; = p.A159= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs561511838, COSV100123814, COSV58761587; called by muse, mutect2
- ENO1 | c.609T>C p.D203= | Silent (SNP) | VAF 104/169 reads (62%) | called by muse, mutect2, varscan2
- KCNG2 | c.108G>A p.A36= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs1220997274; called by muse, mutect2, varscan2
- MCMBP | c.1026C>T p.S342= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs764910740, COSV63510000; called by muse, mutect2, varscan2
- MRPL53 | c.288C>G p.A96= | Silent (SNP) | VAF 46/202 reads (23%) | called by muse, mutect2, varscan2
- OR8K3 | c.774C>T p.Y258= | Silent (SNP) | VAF 34/163 reads (21%) | catalogued as rs149254937; called by muse, mutect2, varscan2
- SSX3 | c.555A>G p.E185= | Silent (SNP) | VAF 84/228 reads (37%) | called by muse, mutect2, varscan2
- SVIL | c.3486C>T p.T1162= (on ENST00000355867 / NM_021738.3; = p.T736= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 116/236 reads (49%) | catalogued as rs1474988764, COSV100881518; called by muse, mutect2, varscan2
- ZC3H12A | c.1443C>T p.T481= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as rs151076639; called by muse, mutect2, varscan2
- CNTN4 | c.56-230A>G | Intron (SNP) | VAF 24/162 reads (15%) | called by muse, mutect2, varscan2
- FAM122C | c.-32A>G | 5'UTR (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- MDGA2 | c.2593+16C>A | Intron (SNP) | VAF 49/104 reads (47%) | called by muse, mutect2, varscan2
- OR2H2 | chr6:29582281 C>T | 5'Flank (SNP) | VAF 29/116 reads (25%) | catalogued as rs891728911; called by muse, mutect2, varscan2
- PDE7A | c.-5A>G | 5'UTR (SNP) | VAF 56/189 reads (30%) | called by muse, mutect2, varscan2
- SCART1 | c.2275+9T>A | Intron (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- USP2 | c.-66T>C | 5'UTR (SNP) | VAF 36/150 reads (24%) | called by muse, mutect2, varscan2
